MMRF case MMRF_1446 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4eb2075e-0aaf-4e0a-98bf-3bd3c90fdc6d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.8 years (25,147 days); ISS stage: I; Days to last known disease status: 1,430 days (3.9 years); Days to last follow up: 1,430 days (3.9 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 99 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 11 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 346 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 106 days; Days to treatment end: 346 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 106 days; Days to treatment end: 162 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 163 days; Days to treatment end: 190 days.
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 190 days; Days to treatment end: 239 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 239 days; Days to treatment end: 346 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 345 days; Days to treatment end: 345 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 346 days; Days to treatment end: 346 days.
   Treatment given: Therapeutic agents: Dexamethasone + Other + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 805 days (2.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 304 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.081 mg/dL; Immunoglobulin G 4.83 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 2.03 µg/mL; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.48 mmol/L; Albumin 46 g/L; Total Protein 6.5 g/dL; Glucose 6.82 mmol/L; C-Reactive Protein 0.02 mg/dL.
- Day 92 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 166 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.161 mg/dL; Immunoglobulin G 2.48 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 6.27 mmol/L.
- Day 182: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 106 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.079 mg/dL; Immunoglobulin G 2 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 3.38 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 86 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 5 g/dL; Glucose 5.12 mmol/L.
- Day 266: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 112 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.589 mg/dL; Immunoglobulin G 2.26 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 114 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 5.6 g/dL; Glucose 4.4 mmol/L.
- Day 366 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 11.4 mg/dL; Immunoglobulin G 3.05 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.63 g/L; Lactate Dehydrogenase 4.3 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 60 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.1 mmol/L; Albumin 26 g/L; Total Protein 4.6 g/dL; Glucose 4.62 mmol/L.
- Day 438 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 28.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.66 mg/dL; Immunoglobulin G 6.63 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 3.57 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 31 g/L; Total Protein 5.5 g/dL; Glucose 5.06 mmol/L.
- Day 533 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 41.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.883 mg/dL; Immunoglobulin G 6.57 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.53 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 5.56 mmol/L.
- Day 639 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 5.37 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.15 mmol/L; Albumin 29 g/L; Total Protein 5.3 g/dL; Glucose 5.56 mmol/L.
- Day 770: M Protein 0.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 107 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.776 mg/dL; Immunoglobulin G 6.94 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.48 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 4.79 mmol/L.
- Day 812 (ECOG 1): M Protein 0.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 119 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 6.11 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 46 g/L; Total Protein 6.5 g/dL; Glucose 5.67 mmol/L.
- Day 891 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 39.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.734 mg/dL; Immunoglobulin G 4.65 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 6.05 mmol/L.
- Day 975 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 84.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.55 mg/dL; Immunoglobulin G 5.15 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.62 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 5.8 g/dL; Glucose 6.22 mmol/L.
- Day 1,066 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.964 mg/dL; Immunoglobulin G 6.49 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.4 mmol/L; Albumin 34 g/L; Total Protein 5.8 g/dL; Glucose 5.39 mmol/L.
- Day 1,150 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.779 mg/dL; Immunoglobulin G 4.2 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 3.53 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.38 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.38 mmol/L; Albumin 35 g/L; Total Protein 5.3 g/dL; Glucose 6.22 mmol/L.
- Day 1,234 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.68 mg/dL; Immunoglobulin G 4.01 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.47 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 36 g/L; Total Protein 5 g/dL; Glucose 8.03 mmol/L.
- Day 1,318 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.802 mg/dL; Immunoglobulin G 6.24 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.4 mmol/L; Albumin 36 g/L; Total Protein 5.9 g/dL; Glucose 5.78 mmol/L.
- Day 1,430 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.827 mg/dL; Immunoglobulin G 7.33 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 5.61 mmol/L.

Other clinical attributes
- Day 1: Weight: 87 kg; Height: 175 cm.

Biospecimens (3 samples)
- Sample MMRF_1446_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1446_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
- Sample MMRF_1446_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 770 days (2.1 years).
